Somatic mutation profile of tumor specimen TCGA-UZ-A9PS-05A (aliquot TCGA-UZ-A9PS-05A-11D-A42J-10) from TCGA case TCGA-UZ-A9PS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II.
Specimen TCGA-UZ-A9PS-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ff917fd-2806-4920-830e-8709986209c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PS-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PS-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99933ac8-9bdb-44a5-bc3c-e0141e18c8ef

The open-access MAF lists 86 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 51, Silent 19, Frame Shift Del 6, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.1921C>A p.Q641K | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); catalogued as rs773687228, COSV99698122; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6275T>C p.M2092T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs921463548, COSV99781776; called by muse, mutect2, varscan2
- APBA2 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as COSV101258117; called by muse, mutect2, varscan2
- APOB | c.3673C>T p.H1225Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99262992; called by muse, mutect2, varscan2
- ASXL2 | c.2856A>T p.L952F | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99709966; called by muse, mutect2, varscan2
- ATP11B | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100017429; called by muse, mutect2, varscan2
- ATP13A1 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV99365498; called by muse, mutect2
- BCAR3 | c.1493A>C p.Q498P | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV99550063; called by muse, mutect2, varscan2
- BCO2 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100730186; called by muse, mutect2, varscan2
- CABIN1 | c.5047G>A p.G1683R | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs529990301, COSV99572525; called by muse, mutect2, varscan2
- CAPRIN2 | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99195402; called by muse, mutect2, varscan2
- CCDC163 | c.432C>A p.C144* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV100516945; called by muse, mutect2, varscan2
- CCNG2 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV100313020; called by muse, mutect2
- CHD3 | c.5492C>T p.A1831V (on ENST00000330494 / NM_001005273.3; = p.A1797V on NM_005852.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1365782473, COSV100177150; called by muse, mutect2, varscan2
- DDHD2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs1380005347, COSV68157505; called by muse, mutect2, varscan2
- ECE1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV99941224; called by muse, mutect2, varscan2
- FAM118B | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100796795; called by muse, mutect2, varscan2
- FLNC | c.5290A>G p.T1764A | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100367515; called by muse, mutect2, varscan2
- FNBP1 | c.143A>T p.N48I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100852536; called by muse, mutect2, varscan2
- GABBR2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV99408907; called by muse, mutect2, varscan2
- GALK2 | c.13A>T p.S5C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV100508493; called by muse, mutect2, varscan2
- GPBP1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.12); catalogued as COSV99302280; called by muse, mutect2, varscan2
- HUS1B | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs575022583, COSV100032458; called by muse, mutect2, varscan2
- ITPRID2 | c.2901C>A p.S967R | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100237750; called by muse, mutect2, varscan2
- KANK2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99624442; called by muse, mutect2
- KCNJ1 | c.145T>G p.C49G | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100131190; called by muse, varscan2
- LRCH3 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100604895; called by muse, mutect2, varscan2
- MCF2L | c.1753A>T p.I585F (on ENST00000375608; = p.I553F on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.045); catalogued as COSV100982046; called by muse, mutect2, varscan2
- MCM3AP | c.2575del p.V859Sfs*7 | Frame Shift Del (DEL) | VAF 42/227 reads (19%) | catalogued as COSV52443787; called by mutect2, pindel, varscan2
- MED13 | c.5815A>G p.S1939G | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV101180705; called by muse, mutect2, varscan2
- MITD1 | c.351A>C p.E117D | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV99175538; called by muse, mutect2, varscan2
- MS4A2 | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99626952; called by muse, mutect2, varscan2
- MYCL | c.307G>A p.E103K (on ENST00000372816 / NM_001033081.3; = p.E133K on NM_005376.5) | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as rs762331288, COSV100862283; called by muse, mutect2, varscan2
- NELL1 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as rs766370630, COSV100118030, COSV54275607; called by muse, mutect2, varscan2
- NME8 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99552636; called by muse, mutect2
- NOTCH4 | c.4522A>C p.S1508R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100900285; called by muse, mutect2, varscan2
- OR4N2 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as COSV100269309; called by muse, mutect2, varscan2
- OVGP1 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100867931; called by muse, mutect2, varscan2
- PABPC4 | c.170T>A p.V57D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100865402; called by muse, mutect2, varscan2
- PATZ1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99315019; called by muse, mutect2, varscan2
- PER2 | c.1046+1G>A p.X349_splice | Splice Site (SNP) | VAF 70/257 reads (27%) | catalogued as COSV99611327; called by muse, mutect2, varscan2
- PIK3R5 | c.2488G>C p.V830L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV99352715; called by muse, mutect2, varscan2
- PRDX1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99423355; called by muse, mutect2, varscan2
- RAD54L2 | c.1267A>T p.K423* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as COSV99620521; called by muse, mutect2, varscan2
- RELN | c.9776C>T p.S3259F | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as COSV100633848, COSV58996462; called by muse, mutect2, varscan2
- RUVBL2 | c.631C>G p.R211G | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV99668753; called by muse, mutect2, varscan2
- SF3B1 | c.2804C>A p.T935K | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59212631; called by muse, mutect2, varscan2
- SLC19A1 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.127); catalogued as COSV100229059; called by muse, mutect2, varscan2
- SLC38A5 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV100476272; called by muse, mutect2
- SMC3 | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100699748; called by muse, mutect2, varscan2
- SPTBN1 | c.4724G>A p.G1575D | Missense Mutation (SNP) | VAF 85/241 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100441510; called by muse, mutect2, varscan2
- SYNE2 | c.10177T>A p.Y3393N | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100646413; called by muse, mutect2, varscan2
- TBC1D23 | c.1718A>G p.D573G (on ENST00000394144 / NM_001199198.3; = p.D558G on NM_018309.5) | Missense Mutation (SNP) | VAF 77/325 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as COSV100792447; called by muse, mutect2, varscan2
- TNIP1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV100161043; called by muse, mutect2, varscan2
- TNIP3 | c.845C>G p.P282R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.246); catalogued as COSV99284217; called by muse, mutect2, varscan2
- TNRC6A | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 43/171 reads (25%) | catalogued as COSV100169299; called by muse, mutect2, varscan2
- UAP1L1 | c.1035C>T p.T345= | Splice Region (SNP) | VAF 16/77 reads (21%) | catalogued as rs1439973745, COSV100814390; called by muse, mutect2, varscan2
- ZNF486 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs909329532, COSV100631017, COSV58717835; called by muse, mutect2, varscan2
- BAP1 | c.1897_1898insCCCGC p.L633Pfs*6 | Frame Shift Ins (INS) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- BMPR1B | c.1111del p.R371Efs*17 | Frame Shift Del (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- CLPTM1L | c.686dup p.N229Kfs*45 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | called by mutect2, pindel, varscan2
- MAST3 | c.1891_1892del p.T631Pfs*31 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- OR1L4 | c.224_228del p.T75Sfs*5 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | called by mutect2, varscan2
- PCDHA1 | c.2234del p.L745Wfs*68 | Frame Shift Del (DEL) | VAF 44/187 reads (24%) | called by mutect2, pindel, varscan2
- PNMA8B | c.1826_1834del p.K609_A612delinsT | In Frame Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- RAG2 | c.91_97del p.F31Kfs*18 | Frame Shift Del (DEL) | VAF 20/77 reads (26%) | called by mutect2, pindel, varscan2
- SLC16A1 | c.1067dup p.C357Lfs*20 | Frame Shift Ins (INS) | VAF 40/161 reads (25%) | called by mutect2, pindel, varscan2
- ABHD17A | c.90G>C p.P30= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV99171193; called by muse, mutect2, varscan2
- ACSS3 | c.1920A>G p.K640= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as COSV99698121, COSV99699553; called by muse, mutect2, varscan2
- ACTR3 | c.744T>C p.D248= | Silent (SNP) | VAF 79/263 reads (30%) | catalogued as COSV99603297; called by muse, mutect2, varscan2
- CCDC183 | c.841C>T p.L281= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs373434330; called by muse, mutect2, varscan2
- DNAJB13 | c.420C>T p.V140= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs754082758, COSV100334438, COSV60269698; called by muse, mutect2, varscan2
- FLNC | c.5289C>T p.P1763= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV100367514; called by muse, mutect2, varscan2
- KAT6A | c.4491C>T p.V1497= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99704211; called by muse, mutect2, varscan2
- KLK2 | c.537G>T p.L179= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV100319793; called by muse, mutect2, varscan2
- KRTAP4-4 | c.159C>A p.T53= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV101180521; called by muse, mutect2, varscan2
- MCM3AP | c.4479G>A p.Q1493= | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as COSV99386345; called by muse, mutect2, varscan2
- MFSD6 | c.1323G>A p.L441= | Silent (SNP) | VAF 71/166 reads (43%) | catalogued as COSV99854953; called by muse, mutect2, varscan2
- NOP9 | c.150T>G p.A50= | Silent (SNP) | VAF 51/158 reads (32%) | catalogued as rs770234990, COSV55384209, COSV55385037, COSV55385547; called by muse, mutect2, varscan2
- OR11A1 | c.714T>A p.A238= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs375156940, COSV101010660; called by muse, mutect2, varscan2
- OR52K1 | c.237G>A p.T79= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs765578382, COSV100297536; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1221C>T p.C407= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV99239764; called by muse, mutect2, varscan2
- RASL12 | c.615C>T p.P205= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99584668; called by muse, mutect2, varscan2
- SIGLEC1 | c.3453G>T p.V1151= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV99163144; called by muse, mutect2, varscan2
- VPS13A | c.1950T>C p.N650= | Silent (SNP) | VAF 61/230 reads (27%) | catalogued as COSV100651948; called by muse, mutect2, varscan2
- ZNF286A | c.1120A>C p.R374= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV101224713; called by muse, mutect2, varscan2
